Somatic mutation profile of tumor specimen ALCH-B369-TTP1-A (aliquot ALCH-B369-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B369, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.5 years (15,531 days).
Specimen ALCH-B369-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df8daeb3-36b7-48fd-aa70-b23d6fcbc29e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B369-NB1-A (Blood Derived Normal), aliquot ALCH-B369-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/351ae0ae-1be5-42d3-b10d-6b5d4cfabf83

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOD1L1 | c.5812G>A p.E1938K | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99240303; called by muse, mutect2, varscan2
- DCAF5 | c.2454T>A p.D818E | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); catalogued as COSV100432855; called by muse, mutect2, varscan2
- H2AC8 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 71/447 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as rs1299699031, COSV55126405; called by muse, mutect2, varscan2
- LCE3B | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 103/285 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.485); catalogued as rs764350326, COSV59500779; called by muse, mutect2, varscan2
- PCDHB10 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 34/1084 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV53377844; called by muse, mutect2
- PTPRT | c.3406G>A p.V1136M | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV61983104, COSV62003144; called by muse, mutect2, varscan2
- ZDHHC7 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs758423291; called by muse, mutect2, varscan2
- ARIH1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- ATP2B3 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 21/323 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2
- DEPP1 | c.596T>G p.L199R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HIPK2 | c.3254C>A p.P1085Q | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRBA2 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- LRBA | c.5104C>A p.P1702T | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated, low confidence (0.67); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PI4KB | c.1038_1045del p.E346Dfs*14 (on ENST00000368873 / NM_001369623.1; = p.E358Dfs*14 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 56/454 reads (12%) | called by mutect2, pindel, varscan2
- RBM10 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 96/736 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RPL5 | c.74-8_79del p.X25_splice | Splice Site (DEL) | VAF 22/187 reads (12%) | called by mutect2, pindel, varscan2
- SCAP | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SH3KBP1 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A3 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 77/560 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- TBC1D24 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 78/540 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPATCH4 | c.48G>A p.G16= | Silent (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- OR2T12 | c.954G>A p.R318= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs756652987, COSV58778477, COSV58780094; called by mutect2, varscan2
- TTN | c.47502T>C p.D15834= (on ENST00000591111; = p.D8410= on NM_003319.4) | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
